Somatic mutation profile of tumor specimen MMRF_1344_1_BM_CD138pos (aliquot MMRF_1344_1_BM_CD138pos_T1_KAS5U_L00642) from MMRF case MMRF_1344, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.2 years (24,170 days).
Specimen MMRF_1344_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26208971-e9f6-438a-80af-2752026faff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1344_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1344_1_PB_Whole_C2_KAS5U_L00650; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14ac0eff-1ebf-4b89-8eeb-cd2d77433782

The open-access MAF lists 164 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, 3'UTR 41, Intron 24, Silent 16, RNA 5, Splice Site 5, 5'UTR 3, 3'Flank 3, 5'Flank 3, Translation Start Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP000812.4 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs562245343, COSV53826154; called by muse, mutect2
- BRWD3 | c.4446G>C p.Q1482H | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as rs1167545341; called by muse, mutect2, varscan2
- CHD9 | c.7744G>A p.D2582N (on ENST00000398510 / NM_001382353.1; = p.D2566N on NM_025134.7) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as rs1234616077; called by muse, mutect2, varscan2
- DNAH1 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs961986537; called by muse, mutect2, varscan2
- EPS15L1 | c.2114T>G p.F705C | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV104372662; called by muse, mutect2, varscan2
- ESYT1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV99920178; called by muse, mutect2, varscan2
- FAM71E2 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs746220526; called by muse, mutect2, varscan2
- GPN1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs139878670; called by muse, mutect2, varscan2
- GTF3A | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.214); catalogued as rs781509543; called by muse, mutect2, varscan2
- HCRTR1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65485911; called by muse, mutect2, varscan2
- IGLL5 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs55812037; called by muse, varscan2
- KMT2A | c.8660G>A p.R2887H | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs782765039, COSV63286107; called by muse, mutect2, varscan2
- MAP4K4 | c.2426C>T p.T809M (on ENST00000347699 / NM_001242559.2; = p.T727M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs372783884; called by muse, mutect2, varscan2
- MGAT5B | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV56926798; called by muse, mutect2, varscan2
- MMP24 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.335); catalogued as rs372495279; called by muse, mutect2, varscan2
- MMRN1 | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs1447050958, COSV53344398; called by muse, mutect2
- MTTP | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs751863175; called by muse, mutect2, varscan2
- NF1 | c.6298C>A p.L2100I (on ENST00000358273 / NM_001042492.3; = p.L2079I on NM_000267.3) | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV62199966; called by muse, mutect2, varscan2
- OBSL1 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs769031522; called by muse, mutect2, varscan2
- OR2L8 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100594211, COSV61725683; called by muse, mutect2, varscan2
- SEMA4C | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs1321069191; called by muse, mutect2, varscan2
- SERPINA10 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs1458964534; called by muse, mutect2, varscan2
- TRMT1 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53400741; called by muse, mutect2, varscan2
- TYROBP | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 26/115 reads (23%) | catalogued as rs1444957322; called by muse, mutect2, varscan2
- WDFY1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs774861163; called by muse, mutect2, varscan2
- ZNF205 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs189840930; called by muse, mutect2, varscan2
- ZNF251 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52959179; called by muse, mutect2, varscan2
- ABCA2 | c.3297G>T p.M1099I (on ENST00000614293; = p.M1069I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- AP1AR | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AR | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AXL | c.1927-1G>T p.X643_splice (on ENST00000301178 / NM_021913.5; = p.X634_splice on NM_001699.6) | Splice Site (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- C3 | c.4198A>T p.M1400L | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1F | c.276-2A>T p.X92_splice | Splice Site (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- CASKIN1 | c.3401A>C p.Q1134P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CGGBP1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMYA5 | c.595T>A p.S199T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DCC | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCPS | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- DIP2C | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FOXA1 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN4 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTD2 | c.139G>C p.A47P | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- IGHA2 | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITPR3 | c.2938A>G p.N980D | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- JAK2 | c.2737T>G p.Y913D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIAA1109 | c.12538G>A p.G4180R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP13-3 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LIMCH1 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- LRRIQ1 | c.3925A>C p.T1309P | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYH8 | c.1651T>A p.F551I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NRXN3 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR10J1 | c.281T>C p.L94S | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR5AK2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGC | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- PRMT1 | c.38A>T p.N13I | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRR32 | c.533T>G p.V178G | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PRSS21 | c.357del p.F120Sfs*7 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- PSORS1C1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- RLF | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- SLC9A3 | c.1713C>A p.D571E | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRGC1 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- UBN2 | c.1436T>C p.F479S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC13C | c.6199+1G>A p.X2067_splice | Splice Site (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- VWA5B2 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF227 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 52/242 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF445 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF687 | c.2549T>A p.L850* | Nonsense Mutation (SNP) | VAF 70/204 reads (34%) | called by muse, mutect2, varscan2
- ZNF695 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNHIT3 | c.286+2T>A p.X96_splice | Splice Site (SNP) | VAF 30/49 reads (61%) | called by muse, mutect2, varscan2
- ACO2 | c.1329C>T p.V443= | Silent (SNP) | VAF 71/133 reads (53%) | called by muse, mutect2, varscan2
- BROX | c.498T>C p.I166= | Silent (SNP) | VAF 58/182 reads (32%) | called by muse, mutect2, varscan2
- CFAP46 | c.7047G>A p.G2349= | Silent (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- CHST1 | c.1059G>A p.S353= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs528515371, COSV100346248; called by muse, mutect2, varscan2
- CNTNAP1 | c.1245C>T p.S415= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as COSV99226179; called by muse, mutect2, varscan2
- CXCL1 | c.54G>T p.V18= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- DCHS1 | c.6063C>T p.R2021= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs779485621, COSV55029666; called by muse, mutect2, varscan2
- EPC2 | c.1323A>G p.T441= | Silent (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- FAT4 | c.11625T>C p.S3875= | Silent (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- IGKJ5 | c.9C>T p.T3= | Silent (SNP) | VAF 137/233 reads (59%) | catalogued as rs375348000; called by muse, mutect2, varscan2
- JAK2 | c.2565T>C p.L855= | Silent (SNP) | VAF 116/173 reads (67%) | called by muse, mutect2, varscan2
- KIF3B | c.2181C>G p.S727= | Silent (SNP) | VAF 49/93 reads (53%) | called by muse, mutect2, varscan2
- NFKBIZ | c.2145T>C p.A715= | Silent (SNP) | VAF 65/191 reads (34%) | called by muse, mutect2, varscan2
- OR2M3 | c.138T>A p.V46= | Silent (SNP) | VAF 57/189 reads (30%) | called by muse, mutect2, varscan2
- PAEP | c.327G>A p.E109= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- TIMD4 | c.369A>G p.V123= | Silent (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- ABI1 | c.*1421T>A | 3'UTR (SNP) | VAF 5/112 reads (4%) | called by muse, mutect2
- AC017076.1 | n.122T>A | RNA (SNP) | VAF 6/86 reads (7%) | catalogued as rs1265951746; called by muse, mutect2
- AC023055.1 | c.973+4267G>C | Intron (SNP) | VAF 65/150 reads (43%) | called by muse, mutect2, varscan2
- AC025538.1 | n.916C>A | RNA (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- ACTN1 | c.105+942A>T | Intron (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- ADAM8 | c.*480G>A | 3'UTR (SNP) | VAF 18/135 reads (13%) | called by muse, varscan2
- ARMC10 | c.*163T>A | 3'UTR (SNP) | VAF 16/285 reads (6%) | called by muse, mutect2
- ATP6V0A2 | c.2176-34T>C | Intron (SNP) | VAF 70/145 reads (48%) | catalogued as rs1315443010; called by muse, mutect2, varscan2
- ATRNL1 | c.*2033T>A | 3'UTR (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- CD177P1 | n.739T>G | RNA (SNP) | VAF 55/160 reads (34%) | called by muse, mutect2, varscan2
- CNOT8 | c.*403C>G | 3'UTR (SNP) | VAF 66/95 reads (69%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.*2603T>G | 3'UTR (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- CRYM | c.*82C>T | 3'UTR (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2, varscan2
- DEK | c.-9-140G>T | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- DISC1 | c.*4321C>A | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- DLD | c.*104G>A | 3'UTR (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- EIF2B5 | c.1770-29G>A | Intron (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- ENTPD5 | chr14:73958706 C>G | 3'Flank (SNP) | VAF 9/35 reads (26%) | catalogued as rs1377831831; called by muse, mutect2, varscan2
- FMO5 | c.-81C>G | 5'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- GABRG2 | c.1248+376C>A | Intron (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2
- GMFG | c.357+131G>A | Intron (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- GPR85 | c.*3301A>T | 3'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2
- GTF2E1 | c.*1128C>T | 3'UTR (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- HMGA2 | c.*1007_*1009del | 3'UTR (DEL) | VAF 5/33 reads (15%) | catalogued as rs971169177; called by pindel, varscan2
- INPP4B | chr4:142026143 T>A | 3'Flank (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- KIAA0825 | c.*852C>A | 3'UTR (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- LAIR1 | c.*222A>G | 3'UTR (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- LATS1 | c.-141+23G>T | Intron (SNP) | VAF 25/36 reads (69%) | called by muse, mutect2, varscan2
- LETM2 | c.1218+129T>C | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- LRFN5 | c.-11C>T | 5'UTR (SNP) | VAF 43/93 reads (46%) | catalogued as COSV99984724; called by muse, mutect2, varscan2
- LTB | c.163-138C>G | Intron (SNP) | VAF 72/191 reads (38%) | called by muse, mutect2, varscan2
- LTB | c.162+156C>T | Intron (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- MCM3AP | c.5039-77C>T | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as rs779338116; called by muse, varscan2
- MEPE | c.108+1071G>C | Intron (SNP) | VAF 62/129 reads (48%) | called by muse, mutect2, varscan2
- MIEF1 | c.*295G>A | 3'UTR (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- MIR3689F | n.12C>A | RNA (SNP) | VAF 48/186 reads (26%) | called by muse, mutect2, varscan2
- MYADML2 | c.*907_*916del | 3'UTR (DEL) | VAF 43/101 reads (43%) | called by mutect2, pindel, varscan2
- NLRP6 | chr11:278493 G>A | 5'Flank (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- OR4C48P | n.428T>A | RNA (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- PCDH19 | c.*667T>G | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- PDE10A | c.*1101C>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- PDE4D | c.456-59902A>G | Intron (SNP) | VAF 80/110 reads (73%) | called by muse, mutect2, varscan2
- PLA2G4E | c.*739C>T | 3'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs761314110; called by muse, varscan2
- PLCB2 | chr15:40284435 G>A | 3'Flank (SNP) | VAF 74/238 reads (31%) | catalogued as rs1200613450; called by muse, mutect2, varscan2
- PPP1R9A | c.*1750T>C | 3'UTR (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- PTCHD4 | c.908-20400A>C | Intron (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- PTGFRN | c.*1524C>T | 3'UTR (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- RAB22A | c.*5434T>C | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- RAB3B | c.*1579T>C | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- RBM15B | c.*4A>T | 3'UTR (SNP) | VAF 96/234 reads (41%) | called by muse, mutect2, varscan2
- RBMS3 | c.*558A>G | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- RIPPLY3 | c.*134A>C | 3'UTR (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- RNF152 | c.*6242C>T | 3'UTR (SNP) | VAF 5/91 reads (5%) | catalogued as rs1293847761; called by muse, mutect2
- RUBCN | c.1261+111G>A | Intron (SNP) | VAF 61/274 reads (22%) | catalogued as COSV99582826; called by muse, mutect2, varscan2
- S1PR3 | c.-147-2810A>T | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- SAYSD1 | c.*482T>G | 3'UTR (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- SEMA5A | c.-77-106T>C | Intron (SNP) | VAF 22/30 reads (73%) | called by muse, varscan2
- SLC10A4 | c.*33G>A | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- SLC17A6 | chr11:22338069 C>A | 5'Flank (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- SLC24A1 | c.*1710G>A | 3'UTR (SNP) | VAF 12/124 reads (10%) | catalogued as rs920568398; called by muse, mutect2
- SLC4A11 | c.1898-36G>A | Intron (SNP) | VAF 38/76 reads (50%) | catalogued as rs372150430; called by muse, mutect2, varscan2
- SMAP1 | c.339-383G>T | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- SNAP29 | c.*910A>T | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- SNX24 | chr5:122845518 C>T | 5'Flank (SNP) | VAF 63/87 reads (72%) | called by muse, mutect2, varscan2
- SPRY4 | c.*2678C>T | 3'UTR (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- TMCO5A | c.*122G>A | 3'UTR (SNP) | VAF 29/83 reads (35%) | catalogued as COSV100148409; called by muse, mutect2, varscan2
- TMEM19 | c.*2869G>A | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- TMEM9 | c.-523A>G | 5'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs1254130692; called by muse, varscan2
- TNS1 | c.*2262T>A | 3'UTR (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- TRIM2 | c.1430-7115A>T | Intron (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*867C>T | 3'UTR (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.*3840T>G | 3'UTR (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- USF2 | c.728-35C>T | Intron (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- WNT11 | c.*480T>C | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- WNT9A | c.*1112G>A | 3'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- ZNF136 | c.*976A>G | 3'UTR (SNP) | VAF 26/139 reads (19%) | catalogued as rs1430164829; called by muse, mutect2, varscan2
- ZNF585B | c.72+8046C>G | Intron (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- ZNF605 | c.*1112A>C | 3'UTR (SNP) | VAF 44/78 reads (56%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.1180+1648C>T | Intron (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
